MMRF case MMRF_1128 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/584d9cab-4f01-42a3-9cea-91ddb1062777

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 48 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 48.6 years (17,765 days); ISS stage: II; Days to last known disease status: 1,691 days (4.6 years); Days to last follow up: 1,691 days (4.6 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 116 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 40 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 117 days.
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 62 days; Days to treatment end: 147 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 214 days; Days to treatment end: 215 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 214 days; Days to treatment end: 214 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 313 days; Days to treatment end: 537 days (1.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 537 days (1.5 years); Days to treatment end: 634 days (1.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 634 days (1.7 years); Days to treatment end: 1,118 days (3.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -30 (ECOG 0): M Protein 4.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.177 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 360 mg/dL; Immunoglobulin G 71.9 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 1.75 g/L; Beta 2 Microglobulin 4.4 µg/mL; Hemoglobin 6.57 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.28 mmol/L; Albumin 31 g/L; Total Protein 12.1 g/dL; Glucose 6.11 mmol/L.
- Day 62 (ECOG 0): M Protein 1.6 g/dL; Hemoglobin 7.75 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 7.5 g/dL; Glucose 4.18 mmol/L.
- Day 104 (ECOG 0): M Protein 1.1 g/dL; Hemoglobin 9.18 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 7.5 g/dL; Glucose 5.67 mmol/L.
- Day 250: Hemoglobin 7.44 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 5.28 mmol/L.
- Day 313 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.989 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.737 mg/dL; Immunoglobulin G 7.17 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 2.27 µg/mL; Hemoglobin 7.32 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.75 mmol/L; Albumin 45 g/L; Total Protein 7.1 g/dL; Glucose 7.04 mmol/L.
- Day 410 (ECOG 1): M Protein 0 g/dL; Hemoglobin 7.32 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.6 mmol/L; Albumin 46 g/L; Total Protein 6.9 g/dL; Glucose 5.45 mmol/L.
- Day 509 (ECOG 0): M Protein 0 g/dL; Hemoglobin 7.87 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.53 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 4.95 mmol/L.
- Day 565 (ECOG 0): Hemoglobin 8.43 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.55 mmol/L; Albumin 44 g/L; Total Protein 7.1 g/dL; Glucose 7.1 mmol/L.
- Day 690 (ECOG 0): M Protein 0 g/dL; Hemoglobin 8.56 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.53 mmol/L; Albumin 44 g/L; Total Protein 7.4 g/dL; Glucose 4.95 mmol/L.
- Day 789: M Protein 0 g/dL; Hemoglobin 8.99 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.58 mmol/L; Albumin 46 g/L; Total Protein 7.6 g/dL; Glucose 7.81 mmol/L.
- Day 873: M Protein 0 g/dL; Hemoglobin 9.42 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.65 mmol/L; Albumin 49 g/L; Total Protein 8 g/dL; Glucose 4.73 mmol/L.
- Day 929: M Protein 0 g/dL; Hemoglobin 8.68 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.65 mmol/L; Albumin 47 g/L; Total Protein 7.4 g/dL; Glucose 4.24 mmol/L.
- Day 1,034 (ECOG 0): M Protein 0 g/dL; Hemoglobin 9.18 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.55 mmol/L; Albumin 45 g/L; Total Protein 7.3 g/dL; Glucose 5.61 mmol/L.
- Day 1,146 (ECOG 0): M Protein 0 g/dL; Hemoglobin 8.87 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.48 mmol/L; Albumin 45 g/L; Total Protein 7.9 g/dL; Glucose 5.17 mmol/L.
- Day 1,236: M Protein 0 g/dL; Hemoglobin 8.8 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.58 mmol/L; Albumin 49 g/L; Total Protein 8 g/dL; Glucose 5.12 mmol/L.
- Day 1,328 (ECOG 0): M Protein 0 g/dL; Hemoglobin 9.24 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.53 mmol/L; Albumin 47 g/L; Total Protein 7.2 g/dL; Glucose 5.23 mmol/L.
- Day 1,418 (ECOG 0): M Protein 0 g/dL; Hemoglobin 8.87 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.53 mmol/L; Albumin 49 g/L; Total Protein 7.5 g/dL; Glucose 4.95 mmol/L.
- Day 1,517 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 1.61 g/L; Immunoglobulin M 0.89 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.5 mmol/L; Albumin 46 g/L; Total Protein 7.7 g/dL; Glucose 5.06 mmol/L.
- Day 1,607 (ECOG 0): M Protein 0 g/dL; Hemoglobin 9.11 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 5.72 mmol/L.
- Day 1,691 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Hemoglobin 8.87 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 7.5 g/dL; Glucose 6.44 mmol/L.

Other clinical attributes
- Day -30: Weight: 78 kg; Height: 179 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Melanoma; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1128_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -30 days.
- Sample MMRF_1128_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -30 days.
